Gene-level copy-number profile of tumor specimen TCGA-13-2060-01A from TCGA case TCGA-13-2060, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.0 years (18,635 days).
Specimen TCGA-13-2060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4f64fc1e-d250-4438-bd6d-c1c4b8f50033.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-2060-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/283e9fe7-0b93-41c4-82db-7d4114bf3684

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,206; copy number 2: 15,779; copy number 3: 19,141; copy number 4: 15,437; copy number 5: 4,744; copy number 6: 1,896; copy number 7: 513; copy number 8: 109; copy number 9: 646; copy number 10: 74; copy number 12: 150; copy number 13: 45; copy number 14: 5; copy number 15: 14; copy number 17: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-2060-01A-01D-0704-01): tumor purity 0.65, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,576 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,713,877–42,996,814, 225 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr1:51,329,654–51,519,266, 5 genes, copy number 10: TTC39A-AS1, EPS15, AL671986.1, RNU6-877P, AC104170.1.
- chr1:90,657,750–92,298,987, 31 genes, copy number 7: SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763, AC091614.1, PHKA1P1, ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P, BRDT, EPHX4, LPCAT2BP, SETSIP, BTBD8, GAPDHP46, PRKAR1AP1, AC104836.1, AL663109.1, C1orf146, ACTBP12, GLMN.
- chr1:143,343,180–156,033,342, 586 genes, copy number 9 (broad region; genes not listed).
- chr2:21,094,101–31,853,423, 223 genes, copy number 7 (broad region; genes not listed).
- chr2:41,819,747–44,772,592, 59 genes, copy number 8 (within-gene range 6–8): LDHAP3, RPS12P4, Y_RNA, LINC01913, RNU4-63P, LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4, COX7A2L, AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT.
- chr8:119,711,830–120,445,402, 12 genes, copy number 8: RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13.
- chr10:22,475,455–24,822,950, 27 genes, copy number 7: AL513128.2, PIP4K2A, AL390318.1, RNU6-413P, ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2, AL512603.1, KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305, AL157385.2.
- chr12:53,739,611–54,803,589, 64 genes, copy number 7 (broad region; genes not listed).
- chr13:64,958,097–67,267,706, 16 genes, copy number 8–14: LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53.
- chr14:42,608,868–42,657,918, 2 genes, copy number 10: AL442163.2, AL442163.3.
- chr18:25,302,126–37,762,131, 170 genes, copy number 8–13 (broad region; genes not listed).
- chr18:38,655,209–39,800,322, 6 genes, copy number 9 (within-gene range 3–9): AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66.
- chr18:63,327,726–71,944,577, 97 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–29,901,869, 53 genes, copy number 8–17: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1.

Autosomal genes at a single copy (total copy number 1): 297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
